Somatic mutation profile of tumor specimen TARGET-10-PASTPT-09A (aliquot TARGET-10-PASTPT-09A-01D) from TARGET case TARGET-10-PASTPT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,774 days).
Specimen TARGET-10-PASTPT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b721e213-343f-4613-afef-b43713ed2229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASTPT-10A (Blood Derived Normal), aliquot TARGET-10-PASTPT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe54b7b3-4fb5-4c88-baad-47d5221b082f

The open-access MAF lists 26 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 6, Silent 5, Nonsense Mutation 4, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AL592490.1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV69426434; called by muse, mutect2, varscan2
- CACNA1D | c.3457G>A p.V1153I (on ENST00000350061 / NM_001128840.3; = p.V1173I on NM_000720.4) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.578); catalogued as rs149170250; called by muse, mutect2, varscan2
- COL12A1 | c.4993G>T p.E1665* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV59400731; called by muse, mutect2, varscan2
- DIDO1 | c.5157_5158insCTCTCCC p.E1720Lfs*72 | Frame Shift Ins (INS) | VAF 36/69 reads (52%) | catalogued as COSV56628081; called by mutect2, pindel, varscan2
- HDLBP | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV60498599; called by muse, mutect2, varscan2
- HIC2 | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV68042511; called by muse, mutect2, varscan2
- MATN3 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV68100209; called by muse, mutect2, varscan2
- NUP155 | c.2504G>A p.G835E (on ENST00000231498 / NM_153485.3; = p.G776E on NM_004298.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.375); catalogued as COSV51531976; called by muse, mutect2, varscan2
- PTPA | c.956G>A p.W319* (on ENST00000337738 / NM_178001.2; = p.W284* on NM_021131.5) | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | catalogued as COSV61235572; called by muse, mutect2, varscan2
- RIPOR3 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as COSV50394625, COSV50400597; called by muse, mutect2, varscan2
- SLFN13 | c.2419A>T p.K807* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV53194456; called by muse, mutect2, varscan2
- SRL | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV68423891; called by muse, mutect2, varscan2
- ACLY | c.2316A>G p.A772= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- COL12A1 | c.4992T>C p.T1664= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- LRP1 | c.5790C>T p.H1930= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs560161034; called by muse, mutect2, varscan2
- RTL1 | c.2034C>T p.N678= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1314230092, COSV101128110; called by muse, mutect2, varscan2
- TBC1D16 | c.888C>T p.C296= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs200643195, COSV60477891; called by muse, mutect2
- ANXA2P2 | n.363A>G | RNA (SNP) | VAF 8/59 reads (14%) | catalogued as rs755130247; called by muse, mutect2, varscan2
- CCSER1 | c.2217+233048C>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CEMIP | c.1797+373C>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- CHCHD3 | c.170-10076A>C | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs12673323, COSV52769412; called by muse, mutect2, varscan2
- CHCHD3 | c.170-11209A>G | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as rs12674366, COSV52769484; called by muse, varscan2
- FAM153CP | chr5:178055744 C>T | 3'Flank (SNP) | VAF 20/34 reads (59%) | catalogued as rs796546309; called by muse, varscan2
- MLIP | c.612+11940G>A | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- PITX2 | c.390+239G>A | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
